Somatic mutation profile of tumor specimen TCGA-CV-A460-01A (aliquot TCGA-CV-A460-01A-21D-A25D-08) from TCGA case TCGA-CV-A460, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G3; Age at diagnosis: 72.7 years (26,539 days).
Specimen TCGA-CV-A460-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 814188f4-9704-4bbe-8fc5-77e1033607cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A460-10A (Blood Derived Normal), aliquot TCGA-CV-A460-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c57c78aa-2b4d-4ed9-8308-c48dc71b60b2

The open-access MAF lists 71 somatic variants for this specimen: 57 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 48, Silent 14, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCB1 | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770289924, COSV99713636; called by muse, mutect2, varscan2
- AJUBA | c.877_878insT p.R293Lfs*13 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as COSV99401099; called by mutect2, pindel, varscan2
- AKAP13 | c.4283C>G p.S1428* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV63467333; called by muse, mutect2, varscan2
- ARMC5 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs1372789325, COSV51659087, COSV99192664; called by muse, mutect2, varscan2
- C2CD3 | c.5576T>G p.L1859R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.403); catalogued as COSV100487057; called by muse, mutect2, varscan2
- CCN5 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1231360660, COSV99509417; called by muse, mutect2, varscan2
- CETN1 | c.49A>G p.R17G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100511378; called by muse, mutect2, varscan2
- CHERP | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99550380; called by muse, mutect2, varscan2
- CHML | c.1502G>A p.C501Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087137, COSV100087608; called by muse, mutect2, varscan2
- CIT | c.1301T>C p.V434A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99950327; called by muse, mutect2, varscan2
- CNBD2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as COSV62587945; called by muse, mutect2, varscan2
- COASY | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99888591; called by muse, mutect2, varscan2
- COMT | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99258749; called by muse, mutect2, varscan2
- DBT | c.555T>C p.N185= | Splice Region (SNP) | VAF 22/125 reads (18%) | catalogued as COSV100923558; called by muse, mutect2, varscan2
- DNAH9 | c.8074T>G p.S2692A | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV99306904; called by muse, mutect2, varscan2
- FAM47A | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100649987; called by muse, mutect2, varscan2
- FOXO3 | c.1949A>G p.N650S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1389576679, COSV100670022; called by mutect2, varscan2
- FZD6 | c.1305C>G p.Y435* | Nonsense Mutation (SNP) | VAF 36/179 reads (20%) | catalogued as COSV100708444; called by muse, mutect2, varscan2
- GABRA4 | c.165G>T p.L55F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51932437, COSV99974332; called by muse, mutect2, varscan2
- GIGYF2 | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV101004535; called by muse, mutect2, varscan2
- HS3ST4 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 44/205 reads (21%) | catalogued as rs267604480, COSV58812934, COSV58826059; called by muse, mutect2, varscan2
- HYLS1 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs752663072, COSV99699946; called by muse, mutect2, varscan2
- JRKL | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs148141652; called by muse, mutect2, varscan2
- KCNG2 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV60267100; called by muse, mutect2
- KIAA0100 | c.4589C>A p.S1530* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as COSV101197359; called by muse, mutect2, varscan2
- LMLN | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as COSV99502516; called by muse, mutect2, varscan2
- LRRC10 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs773536861, COSV64060236; called by muse, mutect2, varscan2
- LRRC66 | c.2587C>A p.P863T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV100603030, COSV58634946; called by muse, mutect2, varscan2
- MCF2 | c.381T>A p.D127E | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV100644927; called by muse, mutect2, varscan2
- MTIF3 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs777543756, COSV66949821; called by muse, mutect2, varscan2
- NIPBL | c.2845A>G p.R949G | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV99241644; called by muse, mutect2, varscan2
- PCLO | c.4520G>T p.R1507I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV100434784, COSV61650200; called by muse, mutect2, varscan2
- PDE10A | c.2084A>G p.E695G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100605357; called by muse, mutect2, varscan2
- PIK3CA | c.3120G>A p.M1040I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV55877469; called by muse, mutect2, varscan2
- PLAA | c.1597A>G p.I533V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101263538; called by muse, mutect2, varscan2
- PLCG1 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs1178732404, COSV99719064; called by muse, mutect2, varscan2
- PRPF4B | c.1220G>C p.R407T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV61784698; called by muse, mutect2, varscan2
- PSG2 | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 118/305 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs141385747, COSV100283617, COSV61546014; called by muse, mutect2, varscan2
- RTP2 | c.479A>G p.E160G | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as COSV100832978; called by muse, mutect2, varscan2
- SGTA | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99682638; called by muse, mutect2, varscan2
- SLC14A1 | c.1007C>G p.P336R | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100425148; called by muse, mutect2, varscan2
- SLC38A10 | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99917703; called by muse, mutect2, varscan2
- STAC | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1007468748, COSV99830350; called by muse, mutect2, varscan2
- SYNE1 | c.14659A>G p.I4887V (on ENST00000367255 / NM_182961.4; = p.I4816V on NM_033071.3) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs1193338175, COSV99572335; called by muse, mutect2, varscan2
- TENT4A | c.2335C>A p.H779N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs748296365, COSV50094534; called by muse, mutect2, varscan2
- TRPA1 | c.803T>G p.V268G | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV100084696; called by muse, mutect2, varscan2
- TTC12 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV100133225, COSV59097372; called by muse, mutect2, varscan2
- UNC13C | c.3234G>T p.M1078I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV52878317; called by muse, mutect2, varscan2
- WDR72 | c.2854T>G p.Y952D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV100854858; called by muse, mutect2, varscan2
- ZNF169 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs779716885, COSV100566311; called by muse, mutect2, varscan2
- ZNF511 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775173794, COSV100756852; called by muse, mutect2, varscan2
- ZNF564 | c.1025G>C p.C342S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757744295, COSV100213227; called by muse, mutect2, varscan2
- ZNF646 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100336769; called by muse, mutect2, varscan2
- ZNF763 | c.901A>G p.I301V (on ENST00000358987 / NM_001367172.2; = p.I304V on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.159); catalogued as COSV100676169; called by muse, mutect2, varscan2
- MRPL37 | c.25_34del p.R9* | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- MYO16 | c.3160_3166del p.D1054Ffs*16 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | called by mutect2, pindel, varscan2
- AGO4 | c.555C>A p.G185= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as COSV100943022; called by muse, mutect2
- DLC1 | c.2712C>T p.P904= (on ENST00000276297 / NM_001348081.2; = p.P467= on NM_006094.5) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs749152245, COSV52305385; called by muse, mutect2, varscan2
- ENDOD1 | c.1461G>T p.R487= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99566674; called by muse, mutect2, varscan2
- FN1 | c.4761T>G p.T1587= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV100117666; called by muse, mutect2, varscan2
- HCN1 | c.2256C>G p.S752= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100301329; called by muse, mutect2, varscan2
- MEP1B | c.1410G>A p.V470= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99328986; called by muse, mutect2, varscan2
- PCDHGA2 | c.1710C>T p.D570= | Silent (SNP) | VAF 83/187 reads (44%) | catalogued as rs770524150, COSV53935080; called by muse, mutect2, varscan2
- RYR3 | c.93G>A p.K31= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV101213251; called by muse, mutect2, varscan2
- SLC24A3 | c.1716C>A p.S572= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100042109; called by muse, mutect2
- SPOCK2 | c.1137C>T p.I379= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs372959015; called by muse, mutect2, varscan2
- TANGO2 | c.348C>T p.Y116= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs199862988, COSV100530106; called by muse, mutect2, varscan2
- UPP2 | c.102G>A p.L34= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99135107; called by muse, mutect2
- VCAM1 | c.726G>A p.V242= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99658736; called by muse, mutect2, varscan2
- WDR90 | c.3744C>A p.L1248= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99553812; called by muse, mutect2, varscan2
